Somatic mutation profile of tumor specimen TCGA-A2-A04V-01A (aliquot TCGA-A2-A04V-01A-21W-A050-09) from TCGA case TCGA-A2-A04V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 39.0 years (14,250 days).
Specimen TCGA-A2-A04V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea22138e-2c9c-4648-8a84-2abaf96295fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A04V-10A (Blood Derived Normal), aliquot TCGA-A2-A04V-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11f23628-c86e-414f-9fde-bdc881ec374b

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 16, Silent 8, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 31/73 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APLP1 | c.1218G>A p.A406= | Splice Region (SNP) | VAF 40/72 reads (56%) | catalogued as rs139176114; called by muse, mutect2, varscan2
- CHD9 | c.226T>G p.S76A | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV68300539; called by muse, mutect2, varscan2
- CPAMD8 | c.399C>G p.I133M (on ENST00000651564; = p.I86M on NM_015692.5) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV52240677; called by muse, mutect2, varscan2
- DRP2 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.588); catalogued as COSV65811996; called by muse, mutect2, varscan2
- FANCC | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.459); catalogued as COSV56667836; called by muse, mutect2, varscan2
- FLG | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs769144771, COSV100911269, COSV100912446; called by muse, mutect2
- FLG2 | c.4661C>T p.S1554F | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.135); catalogued as COSV66174098; called by muse, mutect2
- GRIK5 | c.254T>A p.I85N | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53486598; called by muse, mutect2, varscan2
- KHDRBS1 | c.427_429del p.E143del | In Frame Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs1179505360; called by pindel, varscan2
- KIAA0319L | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs767522854, COSV57843963; called by muse, mutect2, varscan2
- MIF4GD | c.150_151del p.F51Qfs*17 (on ENST00000325102 / NM_001370592.1; = p.F85Qfs*17 on NM_020679.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs1360495300; called by pindel, varscan2
- MRGPRX3 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as rs1224304119, COSV66933604; called by muse, mutect2, varscan2
- OR5L1 | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV61735548; called by muse, varscan2
- PGAP4 | c.741C>A p.H247Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66388500; called by muse, mutect2, varscan2
- SPTB | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1009915997, COSV67629973; called by muse, mutect2, varscan2
- SV2A | c.1456G>A p.V486M | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs782290455, COSV64966034; called by muse, mutect2, varscan2
- TENM4 | c.2228C>A p.T743N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.254); catalogued as COSV53674153; called by muse, mutect2, varscan2
- TMIGD2 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV56669012; called by muse, mutect2, varscan2
- ZDHHC1 | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV62215911; called by muse, mutect2, varscan2
- GPS2 | c.161dup p.E55Gfs*42 | Frame Shift Ins (INS) | VAF 43/91 reads (47%) | called by mutect2, pindel, varscan2
- KANSL1 | c.2769_2770del p.C923* (on ENST00000574590 / NM_001193465.2; = p.C924* on NM_015443.4) | Nonsense Mutation (DEL) | VAF 62/191 reads (32%) | called by pindel, varscan2
- PLEKHA2 | c.526dup p.H176Pfs*26 | Frame Shift Ins (INS) | VAF 32/292 reads (11%) | called by mutect2, pindel, varscan2
- EML3 | c.1995G>A p.L665= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV53875026; called by muse, mutect2, varscan2
- H2AC15 | c.186G>A p.E62= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV57586663; called by muse, mutect2, varscan2
- MROH2B | c.639C>T p.H213= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as rs779094899, COSV68182329; called by muse, mutect2, varscan2
- RHOJ | c.129C>T p.N43= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as rs1207287812, COSV57457287; called by muse, mutect2
- TAPT1 | c.576C>T p.S192= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs1201139768, COSV58824593; called by muse, mutect2, varscan2
- TRMT12 | c.384T>C p.A128= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV60778033; called by muse, mutect2, varscan2
- UBAP2L | c.1863C>T p.F621= | Silent (SNP) | VAF 91/216 reads (42%) | catalogued as COSV55181985; called by muse, mutect2, varscan2
- ZXDA | c.1311G>T p.L437= | Silent (SNP) | VAF 61/149 reads (41%) | catalogued as COSV62388442, COSV62388976; called by muse, mutect2, varscan2
